Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5191, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5191-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

TCGA-BP-5191

Clinical Diagnosis & History:

History incidental left renal mass found on CT.

Specimens Submitted:

- 1: SP: Kidney, left hilar tumor; partial nephrectomy
- 2: SP: Lymph node, left hilar; excision
- 3: SP: Kidney, left cyst wall; excision

DIAGNOSIS:

1. SP: Kidney, left hilar tumor; partial nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 3.2 cm.

Local Invasion (for renal cortical types):

Involves renal sinus fat ✓

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Papillary adenoma. Arteriolonephrosclerosis and chronic inflammation

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3a Tumor invades the adrenal gland or perinephric tissues but not beyond Gerota's fascia

2. SP: Lymph node, left hilar; excision:

Lymph Nodes:

Not involved ✓

Number of nodes examined: 1

[page 2 of 3]
Number of metastatic nodes:0

3. SP: Kidney, left cyst wall; excision:
Benign renal simple cyst. ✓

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1). The specimen is received fresh for frozen section consultation, labeled "left hilar kidney tumor, stitch marks deep margin". It consists of a 8.5 x 6.5 x 2.0 cm wedge shaped portion of kidney and attached perinephric fat, with a suture marking the deep margin. The portion of kidney measures 3.2 x 3.0 x 2.0 cm. The margin is inked black and the specimen is serially sectioned to reveal a 2.5 x 2.2 x 2.0 cm well-circumscribed solid and cystic tumor. The solid areas are bright yellow with areas of hemorrhage. The tumor is distending but not penetrating the capsule. The clearance from the resection margin is 0.3 cm. representative sections of the nearest margin and tumor are submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for TPS. Photographs are taken.

Summary of sections:

FSCA - frozen section control A

FSCB - frozen section control B

T - tumor and margin

RS - representative section uninvolved kidney

2). The specimen is received in formalin, labeled "left hilar lymph node" and consists of a 0.6 x 0.5 x 0.3 cm tan firm possible lymph node, which is entirely submitted.

Summary sections:

LN-lymph node

3). The specimen is received in formalin, labeled "Left kidney cyst wall" and consists of a 1.8 x 1.0 x 0.2 cm purple-gray thin membranous irregular soft issue fragment, with a smooth grossly unremarkable surface. The specimen is entirely submitted.

Summary of sections:

U-- undesignated

Summary of Sections:

Part 1: SP: Kidney, left hilar tumor; partial nephrectomy

Block	Sect. Site	PCs
1	fsca	1
1	fscb	1
1	rs	1
6	t	6

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Part 2: SP: Lymph node, left hilar; excision

Block	Sect. Site	PCs
1	ln	1

Part 3: SP: Kidney, left cyst wall; excision

Block	Sect. Site	PCs
1	u	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) **FROZEN SECTION DIAGNOSIS:** LEFT HILAR KIDNEY TUMOR. RENAL CELL CARCINOMA, CLEAR CELL TYPE, MARGIN OF BENIGN. **PERMANENT DIAGNOSIS:** SAME

Source: NCI Genomic Data Commons file 30103538-9448-4b6b-86e8-fc5df4c08b6b (TCGA-BP-5191.F091F75D-9AB6-42E3-9465-84D024403F0B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).